Somatic mutation profile of tumor specimen TCGA-ZF-AA4X-01A (aliquot TCGA-ZF-AA4X-01A-11D-A38G-08) from TCGA case TCGA-ZF-AA4X, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 56.3 years (20,579 days).
Specimen TCGA-ZF-AA4X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68fdd037-7c5e-490c-a330-377d3277b0e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-AA4X-10A (Blood Derived Normal), aliquot TCGA-ZF-AA4X-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89936855-2392-479a-8873-2ca5ad849daf

The open-access MAF lists 690 somatic variants for this specimen: 501 protein-altering or splice-affecting, 178 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 439, Silent 178, Nonsense Mutation 45, Splice Site 10, Splice Region 4, Intron 4, 3'UTR 3, 5'UTR 2, Frame Shift Ins 1, Translation Start Site 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LDLR | c.1757C>G p.S586* | Nonsense Mutation (SNP) | VAF 31/173 reads (18%) | catalogued as rs1555806455, CM0911491, CM091501, COSV99369950; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 22/52 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 17/53 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs112431538, CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; ClinVar: drug response / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 93/217 reads (43%) | catalogued as rs869312782, COSV52692559, COSV52721885, COSV53153630, COSV53758203; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2671G>A p.E891K | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV55951056; called by muse, mutect2
- ABCC3 | c.487-1G>A p.X163_splice | Splice Site (SNP) | VAF 8/122 reads (7%) | catalogued as COSV53321527; called by muse, mutect2
- ABTB1 | c.769C>A p.L257I (on ENST00000232744 / NM_172027.3; = p.L115I on NM_032548.3) | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV51741590; called by muse, mutect2, varscan2
- AC004076.1 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious, low confidence (0.02); catalogued as COSV58091052; called by muse, mutect2, varscan2
- AC008397.2 | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs763707510, COSV53206848; called by muse, mutect2, varscan2
- ACAP1 | c.1285G>C p.E429Q | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV50135848, COSV99341650; called by muse, mutect2, varscan2
- ACBD5 | c.1204G>A p.E402K (on ENST00000375888 / NM_001352568.1; = p.E393K on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.167); catalogued as rs777230785, COSV65519169; ClinVar: uncertain significance; called by muse, varscan2
- ACBD5 | c.1147G>C p.D383H (on ENST00000375888 / NM_001352568.1; = p.D374H on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/192 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65519325; called by muse, varscan2
- ACKR1 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 19/296 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs150917132; called by muse, mutect2
- ADGRD1 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as rs953457196, COSV55445226; called by mutect2, varscan2
- ADGRG6 | c.2636C>T p.S879L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.981); catalogued as COSV51592131; called by muse, mutect2, varscan2
- AFDN | c.205C>G p.Q69E | Missense Mutation (SNP) | VAF 129/250 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as COSV60044420; called by muse, mutect2, varscan2
- AGO3 | c.2527C>G p.L843V | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.354); catalogued as COSV55793396; called by muse, mutect2, varscan2
- AHRR | c.87G>C p.K29N | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1217726156, COSV57086038; called by muse, mutect2, varscan2
- ALOXE3 | c.2129C>T p.S710F | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59075665; called by muse, mutect2, varscan2
- ANGEL1 | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs761645742, COSV51873285; called by mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6511C>G p.Q2171E | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.237); catalogued as COSV51846849; called by muse, mutect2, varscan2
- ANKRD11 | c.4579G>A p.D1527N | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as rs777979146, COSV56360766; called by muse, mutect2, varscan2
- AOC2 | c.1258C>T p.P420S | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as rs1433021939, COSV53199160; called by muse, mutect2, varscan2
- APCDD1 | c.706C>G p.H236D | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.498); catalogued as COSV62372486; called by muse, mutect2, varscan2
- APCS | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.166); catalogued as COSV54818025; called by muse, mutect2, varscan2
- APOL3 | c.841C>G p.L281V (on ENST00000349314 / NM_145640.2; = p.L210V on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.03); catalogued as COSV62579739; called by muse, mutect2, varscan2
- APPBP2 | c.781G>C p.E261Q | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.775); catalogued as COSV50026672; called by muse, mutect2
- ARHGAP35 | c.975C>G p.I325M | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV68329112; called by muse, mutect2, varscan2
- ARHGEF12 | c.3095G>C p.R1032T | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV63104617; called by muse, mutect2, varscan2
- ARHGEF12 | c.3322C>T p.Q1108* | Nonsense Mutation (SNP) | VAF 17/75 reads (23%) | catalogued as COSV100754718, COSV100754934; called by muse, mutect2, varscan2
- ARHGEF7 | c.1783C>A p.H595N (on ENST00000375741 / NM_001113511.2; = p.H417N on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as rs1282640905, COSV54543172, COSV99521504; called by muse, mutect2, varscan2
- ARID1A | c.2144C>T p.S715L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1387691435, COSV61375961; called by muse, mutect2, varscan2
- ARID4B | c.2920G>A p.E974K | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.952); catalogued as COSV51603059; called by muse, mutect2, varscan2
- ARMC9 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV63020876; called by muse, mutect2
- ASAP1 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63048471; called by muse, mutect2, varscan2
- ASXL3 | c.4834G>A p.D1612N | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV52465911; called by muse, mutect2, varscan2
- ATAD2 | c.1383-1G>A p.X461_splice | Splice Site (SNP) | VAF 22/56 reads (39%) | catalogued as COSV54880763; called by muse, mutect2, varscan2
- ATF7IP | c.572C>G p.S191C | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.247); catalogued as COSV53767787; called by muse, mutect2, varscan2
- ATG2A | c.4033G>A p.E1345K | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT tolerated (0.72); PolyPhen benign (0.018); catalogued as COSV65966813; called by muse, mutect2, varscan2
- ATM | c.3622G>A p.D1208N | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as COSV53743783, COSV53761931; called by muse, mutect2, varscan2
- ATP10D | c.2551G>A p.D851N | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs1320373884, COSV56707328; called by muse, mutect2, varscan2
- ATP8A2 | c.2524G>A p.E842K | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54951749; called by muse, mutect2, varscan2
- ATXN2 | c.1624G>C p.D542H (on ENST00000550104; = p.D382H on NM_002973.4) | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66483184; called by muse, mutect2, varscan2
- ATXN7L3 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); catalogued as COSV66988489, COSV66988637; called by muse, mutect2, varscan2
- AUTS2 | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | catalogued as COSV100717110; called by muse, mutect2, varscan2
- AUTS2 | c.1069C>A p.Q357K | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as COSV61400743; called by muse, mutect2, varscan2
- B3GALNT1 | c.337C>G p.L113V | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.189); catalogued as COSV57580211; called by muse, mutect2, varscan2
- BAIAP2 | c.441G>C p.K147N | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58335356; called by muse, mutect2, varscan2
- BCL9L | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs1300515083, COSV58311382; called by muse, mutect2, varscan2
- BCOR | c.4891G>A p.D1631N (on ENST00000378444 / NM_001123385.2; = p.D1597N on NM_017745.6) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as rs769982436, COSV60707126; called by muse, mutect2, varscan2
- BICC1 | c.772C>T p.Q258* | Nonsense Mutation (SNP) | VAF 13/78 reads (17%) | catalogued as rs1248687073, COSV99570539; called by muse, mutect2, varscan2
- BIRC6 | c.8581G>A p.E2861K | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70199158; called by muse, mutect2, varscan2
- BMP6 | c.858-1G>C p.X286_splice | Splice Site (SNP) | VAF 28/174 reads (16%) | catalogued as COSV51665202; called by muse, mutect2, varscan2
- BPHL | c.555G>A p.W185* | Nonsense Mutation (SNP) | VAF 69/180 reads (38%) | catalogued as COSV100984479; called by muse, mutect2, varscan2
- BUD13 | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV52768297; called by muse, mutect2, varscan2
- C11orf42 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs1204226270, COSV99792103; called by muse, mutect2
- C14orf93 | c.1341C>G p.F447L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as COSV52985239; called by muse, mutect2, varscan2
- C17orf80 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); catalogued as rs750889727, COSV52146075; called by muse, mutect2, varscan2
- C2orf16 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV68646058; called by muse, mutect2, varscan2
- C3orf52 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99332456; called by muse, mutect2
- C3orf62 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.127); catalogued as rs774667709, COSV55537033; called by muse, mutect2, varscan2
- C7 | c.785T>A p.F262Y | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57474263; called by muse, mutect2, varscan2
- C8orf33 | c.593G>C p.R198T | Missense Mutation (SNP) | VAF 39/226 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV58895601; called by muse, mutect2, varscan2
- CACNA1H | c.6490G>A p.E2164K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as COSV99326736; called by muse, mutect2
- CADPS | c.3253G>A p.E1085K | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1298638581, COSV51879653; called by muse, mutect2, varscan2
- CAMSAP1 | c.847C>G p.L283V | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.203); catalogued as rs1341073536, COSV56722521; called by muse, mutect2, varscan2
- CBFB | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51998344; called by muse, mutect2, varscan2
- CBL | c.2393C>A p.S798Y | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as COSV50636749, COSV50668623; called by muse, mutect2, varscan2
- CCDC34 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.802); catalogued as COSV58725747, COSV58726475; called by muse, mutect2, varscan2
- CCDC51 | c.337C>G p.R113G | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56489563, COSV56492712; called by muse, mutect2, varscan2
- CCDC57 | c.2425C>A p.P809T | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.302); catalogued as COSV66437732; called by muse, mutect2, varscan2
- CCDC62 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.135); catalogued as rs772319364, COSV53433484; called by muse, mutect2, varscan2
- CCDC80 | c.2716C>T p.Q906* | Nonsense Mutation (SNP) | VAF 13/76 reads (17%) | catalogued as rs1281258224, COSV52820015; called by muse, mutect2, varscan2
- CCNE1 | c.775C>G p.L259V | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV52904405, COSV52904642; called by muse, mutect2, varscan2
- CCNE2 | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 48/111 reads (43%) | catalogued as COSV100353765; called by muse, varscan2
- CCNJL | c.612G>T p.L204F | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.044); catalogued as COSV99979491; called by muse, mutect2
- CCNL2 | c.371C>A p.S124* | Nonsense Mutation (SNP) | VAF 13/80 reads (16%) | catalogued as COSV100784978; called by muse, mutect2, varscan2
- CCT7 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.942); catalogued as COSV57822079, COSV57823955; called by muse, varscan2
- CDC16 | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.231); catalogued as COSV52959528; called by muse, mutect2, varscan2
- CDH8 | c.2005G>A p.D669N | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54866839; called by muse, mutect2, varscan2
- CDK12 | c.1485G>C p.L495F | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.085); catalogued as COSV70999047; called by muse, mutect2
- CDK9 | c.243G>C p.L81F | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1426209808, COSV64723750, COSV64724038; called by muse, mutect2, varscan2
- CDKL3 | c.530C>G p.S177C | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as rs1244665263, COSV54743322, COSV99527871; called by muse, mutect2, varscan2
- CEACAM7 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV50072597; called by muse, mutect2, varscan2
- CECR2 | c.3140C>T p.S1047L (on ENST00000342247 / NM_001290047.2; = p.S863L on NM_001290046.1) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs574553165, COSV52840788, COSV52841035; called by muse, mutect2, varscan2
- CEP350 | c.4704G>C p.K1568N | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as COSV62602339; called by muse, mutect2, varscan2
- CEP85 | c.114C>G p.I38M | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV53329297; called by muse, mutect2, varscan2
- CES2 | c.1114C>G p.L372V | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.19); catalogued as COSV57696855; called by muse, mutect2
- CFAP161 | c.830C>A p.S277Y | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV54429234; called by muse, mutect2, varscan2
- CFHR3 | c.252C>T p.L84= | Splice Region (SNP) | VAF 15/40 reads (38%) | catalogued as COSV66402164; called by muse, mutect2, varscan2
- CFHR4 | c.1324G>A p.D442N (on ENST00000367416 / NM_001201551.2; = p.D196N on NM_006684.5) | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.047); catalogued as COSV52228422; called by muse, mutect2, varscan2
- CHD9 | c.940C>G p.H314D | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV101272136; called by muse, mutect2
- CHRNB1 | c.1100G>A p.R367K | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.472); catalogued as COSV60140216, COSV60141157; called by muse, mutect2
- CLCA4 | c.2470G>T p.E824* | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | catalogued as COSV100991115; called by muse, mutect2, varscan2
- CLCN7 | c.170G>C p.G57A | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV51970473; called by muse, mutect2, varscan2
- CLCNKB | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65160475; called by muse, mutect2, varscan2
- CLDN12 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV55306964; called by muse, mutect2, varscan2
- CLEC7A | c.650C>T p.S217F (on ENST00000304084 / NM_197947.3; = p.S171F on NM_022570.5) | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.854); catalogued as COSV53722325; called by muse, varscan2
- CLSTN2 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs774984260, COSV101515516, COSV71720851; called by muse, mutect2, varscan2
- CNTN3 | c.2788G>A p.E930K | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as rs747386697, COSV55171128; called by muse, mutect2, varscan2
- COL14A1 | c.1007C>G p.S336C | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.43); catalogued as rs749156062, COSV52854257; called by muse, mutect2, varscan2
- COL15A1 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.833); catalogued as rs755342492, COSV66644625; called by muse, mutect2, varscan2
- COL25A1 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.995); catalogued as rs1368562033, COSV67650111; called by muse, mutect2, varscan2
- COL4A1 | c.4330C>T p.H1444Y | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65425563; called by muse, mutect2
- COL6A6 | c.159G>C p.M53I | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV62025082; called by muse, mutect2, varscan2
- CSMD3 | c.7321G>A p.E2441K (on ENST00000297405 / NM_001363185.1; = p.E2337K on NM_052900.3) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.981); catalogued as rs767314472, COSV52128371, COSV52178743; called by muse, mutect2, varscan2
- CTNND1 | c.1712C>T p.S571L | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV62383445; called by muse, mutect2, varscan2
- CTNND2 | c.1510C>T p.R504* | Nonsense Mutation (SNP) | VAF 50/149 reads (34%) | catalogued as COSV58892739; called by muse, mutect2, varscan2
- CXorf58 | c.164C>G p.S55C | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV64858170; called by muse, mutect2, varscan2
- CYB5D2 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56800934; called by muse, mutect2, varscan2
- CYP8B1 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV60226340; called by muse, mutect2
- DAB2IP | c.596G>A p.R199Q (on ENST00000408936; = p.R171Q on NM_032552.3) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs567507053, COSV52259109; called by muse, varscan2
- DAXX | c.1763C>T p.S588F | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV56469262, COSV56473551; called by muse, mutect2
- DCAF6 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.472); catalogued as COSV56578642; called by muse, mutect2, varscan2
- DCBLD2 | c.1343G>A p.G448E | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100471420, COSV58789505; called by muse, mutect2, varscan2
- DENND2C | c.1342G>A p.E448K (on ENST00000393274 / NM_001256404.2; = p.E391K on NM_198459.4) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as rs536238659, COSV67921725; called by muse, mutect2, varscan2
- DGKG | c.1921G>C p.D641H | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53969346, COSV99403346; called by muse, mutect2
- DHRS1 | c.657C>T p.F219= | Splice Region (SNP) | VAF 19/158 reads (12%) | catalogued as COSV99852305; called by muse, mutect2
- DHX32 | c.1365G>C p.L455F | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52940170; called by muse, mutect2, varscan2
- DHX8 | c.3010G>A p.E1004K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52253311; called by muse, mutect2, varscan2
- DIAPH2 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61261300, COSV61263823; called by muse, mutect2, varscan2
- DOCK11 | c.5995G>A p.E1999K | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.602); catalogued as COSV52238843; called by muse, mutect2, varscan2
- DOCK7 | c.2374C>G p.L792V | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV52005383; called by muse, mutect2, varscan2
- DOCK8 | c.936C>G p.F312L | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66634023; called by muse, mutect2, varscan2
- DVL2 | c.976G>C p.E326Q | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50035865; called by muse, mutect2, varscan2
- DVL2 | c.900G>A p.M300I | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV50035881; called by muse, mutect2, varscan2
- DXO | c.1051C>T p.H351Y | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756390922, COSV61713606; called by muse, mutect2, varscan2
- DYNC1H1 | c.12064G>A p.E4022K | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV64136915; called by muse, mutect2, varscan2
- E2F7 | c.220G>C p.D74H | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV59739872; called by muse, mutect2, varscan2
- ECH1 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as rs1193332928, COSV55489212; called by muse, mutect2, varscan2
- EFNA5 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV60949656; called by muse, mutect2, varscan2
- EHD4 | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779208576, COSV55004788; called by muse, mutect2, varscan2
- EIF2B5 | c.2068C>G p.L690V (on ENST00000647909; = p.L682V on NM_003907.3) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV56604535; called by muse, mutect2, varscan2
- EIF4G1 | c.4480G>T p.E1494* (on ENST00000346169 / NM_198241.3; = p.E1299* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 9/72 reads (13%) | catalogued as COSV100071819; called by muse, mutect2, varscan2
- EIF5 | c.1183G>C p.E395Q | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as COSV53685196; called by muse, varscan2
- ELF3 | c.414G>C p.W138C | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.921); catalogued as COSV62837294, COSV62838315; called by muse, mutect2, varscan2
- ELN | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52710238; called by muse, mutect2, varscan2
- ELOA2 | c.1379C>G p.S460* | Nonsense Mutation (SNP) | VAF 42/116 reads (36%) | catalogued as COSV55293914, COSV99796656; called by muse, mutect2, varscan2
- EML5 | c.2639C>G p.S880C | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61344942, COSV61345450; called by muse, mutect2, varscan2
- EP400 | c.3129C>A p.V1043= | Splice Region (SNP) | VAF 14/35 reads (40%) | catalogued as rs759040778, COSV57772019; called by muse, mutect2, varscan2
- EVC2 | c.3707C>A p.S1236Y | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.174); catalogued as COSV60393740; called by muse, mutect2, varscan2
- EXOSC1 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV58355664; called by muse, mutect2, varscan2
- EZR | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV61453753; called by muse, mutect2, varscan2
- FAM184A | c.1021C>G p.Q341E | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.977); catalogued as rs1036865522, COSV100138204, COSV58854362; called by muse, mutect2, varscan2
- FASTKD5 | c.1192C>G p.L398V | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753715819, COSV53906061; called by muse, mutect2, varscan2
- FAT4 | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.046); catalogued as COSV67886458; called by muse, mutect2, varscan2
- FAXC | c.544C>T p.H182Y | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.131); catalogued as COSV67602145, COSV67602182; called by muse, mutect2, varscan2
- FBLN2 | c.2671C>T p.Q891* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as rs1343750129, COSV55491653; called by muse, mutect2, varscan2
- FBN3 | c.8312G>A p.G2771E | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53664220; called by muse, mutect2, varscan2
- FBP2 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV64694631; called by muse, mutect2
- FBXO46 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV58348614; called by muse, mutect2, varscan2
- FERMT2 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.247); catalogued as COSV58404908, COSV58406776; called by muse, mutect2, varscan2
- FGF12 | c.563G>C p.R188T (on ENST00000454309 / NM_021032.5; = p.R126T on NM_004113.6) | Missense Mutation (SNP) | VAF 66/179 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV53151914, COSV53164870; called by muse, mutect2, varscan2
- FGL1 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 67/115 reads (58%) | catalogued as COSV67712596; called by muse, mutect2, varscan2
- FMO3 | c.1542G>C p.W514C | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV63007197; called by muse, mutect2, varscan2
- FRAS1 | c.426C>A p.F142L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV53609853; called by muse, mutect2, varscan2
- FUT2 | c.902G>A p.G301E | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1173855229, COSV67179286; called by muse, mutect2, varscan2
- GALNT15 | c.71G>C p.G24A | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.207); catalogued as COSV60216975; called by muse, mutect2, varscan2
- GART | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100738190; called by muse, mutect2
- GATAD2B | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64084142; called by muse, mutect2
- GCC1 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58462580; called by muse, mutect2, varscan2
- GOLGA2 | c.2290C>T p.Q764* | Nonsense Mutation (SNP) | VAF 17/33 reads (52%) | catalogued as rs1372642884, COSV100359932; called by muse, mutect2, varscan2
- GON4L | c.4180C>T p.Q1394* | Nonsense Mutation (SNP) | VAF 20/93 reads (22%) | catalogued as COSV99674330; called by muse, mutect2, varscan2
- GON4L | c.3359C>G p.S1120* | Nonsense Mutation (SNP) | VAF 31/104 reads (30%) | catalogued as COSV99674335; called by muse, mutect2, varscan2
- GPATCH8 | c.2136G>C p.K712N | Missense Mutation (SNP) | VAF 25/247 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.941); catalogued as COSV59194872; called by muse, mutect2, varscan2
- GRIK1 | c.1501G>A p.D501N | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58710747; called by muse, mutect2, varscan2
- GRN | c.289C>T p.H97Y | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV50007128; called by muse, mutect2, varscan2
- GSN | c.528C>G p.F176L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.447); catalogued as COSV57997380; called by muse, mutect2, varscan2
- GSTA1 | c.352G>C p.D118H | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV58015247; called by muse, mutect2, varscan2
- H1-2 | c.516G>C p.K172N | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59190705, COSV59193232; called by muse, mutect2, varscan2
- H2AC11 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.778); catalogued as rs1452305503, COSV60362126; called by muse, mutect2, varscan2
- H2AC16 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.056); catalogued as rs1416465272, COSV58900004, COSV58901260; called by muse, mutect2, varscan2
- H2BC21 | c.25C>G p.P9A | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.147); catalogued as COSV58611973, COSV58613463; called by muse, mutect2, varscan2
- H2BC9 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.251); catalogued as COSV55099863, COSV55100002; called by muse, mutect2, varscan2
- H3C2 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.109); catalogued as rs753823527, COSV52518737; called by muse, mutect2, varscan2
- HDAC6 | c.1031G>A p.G344E | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61928871; called by muse, mutect2, varscan2
- HECTD1 | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV67946296; called by muse, mutect2
- HECTD2 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53220988; called by muse, mutect2, varscan2
- HOXB13 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.904); catalogued as COSV51705970; called by muse, varscan2
- HOXB7 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.487); catalogued as COSV53310460; called by muse, mutect2, varscan2
- HSP90AB1 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs772738556, COSV62336868; called by muse, mutect2
- HSPA1L | c.1423C>G p.Q475E | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.156); catalogued as COSV65149039; called by muse, mutect2, varscan2
- HTR3A | c.1179C>G p.D393E | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV55469442; called by muse, mutect2, varscan2
- IFT74 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.042); catalogued as COSV66259478; called by muse, mutect2, varscan2
- IGHE | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs782245796; called by muse, mutect2, varscan2
- IMPA2 | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs988651206, COSV52319551; called by muse, mutect2
- IMPG1 | c.482G>C p.R161T | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV64057681; called by muse, mutect2, varscan2
- INPP5K | c.1052C>T p.S351L | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV57440964; called by muse, mutect2, varscan2
- ITGBL1 | c.76C>G p.Q26E | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV66023103; called by muse, mutect2, varscan2
- ITLN1 | c.851C>A p.S284Y | Missense Mutation (SNP) | VAF 46/80 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV58275089; called by muse, mutect2, varscan2
- ITPR2 | c.6910C>G p.L2304V | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.83); PolyPhen benign (0.123); catalogued as COSV101190118, COSV67269223, COSV67272731; called by muse, mutect2, varscan2
- JMY | c.1694-1G>T p.X565_splice | Splice Site (SNP) | VAF 5/26 reads (19%) | catalogued as COSV68659313, COSV68660939; called by muse, mutect2
- JPT2 | c.528G>C p.K176N | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV50188829; called by muse, mutect2, varscan2
- KBTBD8 | c.1726G>A p.D576N | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.398); catalogued as COSV55128444; called by muse, mutect2, varscan2
- KCNA5 | c.923C>G p.S308C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.312); catalogued as COSV52905647; called by muse, mutect2, varscan2
- KCNH8 | c.2581G>C p.E861Q | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV60463628; called by muse, mutect2, varscan2
- KCNK5 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1395030491, COSV63988892; called by muse, mutect2, varscan2
- KCTD2 | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56902856; called by muse, mutect2, varscan2
- KDM1B | c.1941G>C p.K647N (on ENST00000449850; = p.K414N on NM_153042.4) | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV52810639, COSV52812509; called by muse, mutect2, varscan2
- KIF14 | c.4588C>G p.L1530V | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.99); PolyPhen benign (0.112); catalogued as COSV66261704; called by muse, mutect2, varscan2
- KIF24 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV61454929; called by muse, mutect2, varscan2
- KIFAP3 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV63033643; called by muse, mutect2, varscan2
- KIFC3 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.364); catalogued as COSV65550267; called by muse, mutect2, varscan2
- KIN | c.665C>A p.S222* | Nonsense Mutation (SNP) | VAF 47/122 reads (39%) | catalogued as COSV101092576; called by muse, mutect2, varscan2
- KIR3DL2 | c.1310G>T p.R437I | Missense Mutation (SNP) | VAF 44/258 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54391974, COSV99551778; called by muse, mutect2, varscan2
- KLHDC4 | c.671C>T p.S224L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs1023529190, COSV54508071; called by muse, mutect2, varscan2
- KNG1 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV53977718; called by muse, mutect2, varscan2
- KRT75 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52872612, COSV52872742; called by muse, mutect2, varscan2
- KRT79 | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57940029; called by muse, mutect2, varscan2
- LAMA1 | c.3952G>C p.E1318Q | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as COSV67536886; called by muse, mutect2, varscan2
- LAMA3 | c.3467C>T p.S1156F | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.751); catalogued as COSV58065301; called by muse, mutect2, varscan2
- LAMP1 | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.462); catalogued as COSV58150069; called by muse, mutect2, varscan2
- LAMP5 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.883); catalogued as rs1450888902, COSV55716407; called by muse, mutect2, varscan2
- LARP1B | c.267G>C p.E89D | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1342189491, COSV52797562; called by muse, mutect2
- LCMT2 | c.940G>C p.G314R | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59790406; called by muse, mutect2, varscan2
- LCN6 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs777381668, COSV57910339; called by muse, mutect2, varscan2
- LCOR | c.2154G>A p.M718I | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs768753233, COSV53715839; called by muse, mutect2, varscan2
- LRATD1 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54472761, COSV54473926; called by muse, mutect2, varscan2
- LRFN2 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.564); catalogued as rs1387751774, COSV57833497; called by muse, mutect2
- LRRC7 | c.1135-1G>A p.X379_splice (on ENST00000651989 / NM_001370785.2; = p.X346_splice on NM_001330635.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 6/96 reads (6%) | catalogued as COSV50456230; called by muse, mutect2
- LRRIQ1 | c.4288G>C p.E1430Q | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV67830644, COSV67838669; called by muse, mutect2, varscan2
- LRRN4CL | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs151072274, COSV54015560; called by muse, mutect2, varscan2
- MAGEB16 | c.740G>A p.R247K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.07); catalogued as COSV67873543, COSV67874256; called by muse, mutect2, varscan2
- MAN2B1 | c.2602C>T p.Q868* | Nonsense Mutation (SNP) | VAF 4/13 reads (31%) | catalogued as rs1179633090, COSV99666975; called by muse, mutect2
- MAP1A | c.6515C>T p.S2172L | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1476966164, COSV55808706; called by muse, mutect2
- MAP3K5 | c.3547G>A p.E1183K | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV62889143; called by muse, mutect2, varscan2
- MAP4 | c.3423G>C p.Q1141H | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53137662, COSV99275580; called by muse, varscan2
- MBTPS2 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV63411518; called by muse, mutect2, varscan2
- MCC | c.1181G>C p.R394T | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as COSV56728832; called by muse, mutect2, varscan2
- MCF2L | c.1030C>T p.Q344* (on ENST00000375608; = p.Q312* on NM_024979.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 42/79 reads (53%) | catalogued as COSV100982573, COSV100983098; called by muse, mutect2, varscan2
- MCM7 | c.918G>T p.M306I | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV57996355; called by muse, mutect2, varscan2
- MCTP1 | c.1586G>C p.R529T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.055); catalogued as COSV56515483; called by muse, mutect2, varscan2
- MDM2 | c.824C>G p.S275* | Nonsense Mutation (SNP) | VAF 3/40 reads (8%) | catalogued as COSV99254563; called by muse, mutect2
- MED13 | c.360C>G p.F120L | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV67263509; called by muse, mutect2, varscan2
- MEF2D | c.15G>T p.K5N | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV61728239; called by muse, mutect2, varscan2
- MERTK | c.2691C>G p.I897M | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.285); catalogued as COSV54928919, COSV54929144; called by muse, mutect2, varscan2
- MFSD6 | c.1687C>T p.P563S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV55622584; called by muse, mutect2, varscan2
- MGAT4C | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.053); catalogued as rs866745321, COSV59832581; called by muse, mutect2, varscan2
- MGST3 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.087); catalogued as rs755175792, COSV63321112; called by muse, mutect2, varscan2
- MIA2 | c.248C>G p.S83C | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54493101; called by muse, mutect2, varscan2
- MLF1 | c.192G>C p.L64F | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT tolerated (0.2); PolyPhen benign (0.041); catalogued as COSV63033556; called by muse, mutect2, varscan2
- MPI | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100086325, COSV60396803; called by muse, mutect2, varscan2
- MROH2B | c.2650G>C p.E884Q | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.042); catalogued as COSV68184004; called by muse, mutect2, varscan2
- MSH4 | c.1129C>G p.Q377E | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV54202018, COSV99590584; called by muse, mutect2, varscan2
- MT4 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV54642354; called by muse, mutect2, varscan2
- MUC16 | c.33977C>G p.S11326C | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.753); catalogued as COSV67465395; called by muse, mutect2, varscan2
- MUC17 | c.2219C>G p.S740* | Nonsense Mutation (SNP) | VAF 34/402 reads (8%) | catalogued as COSV100071128; called by muse, mutect2
- MUC21 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 52/261 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.075); catalogued as COSV66220835; called by muse, mutect2, varscan2
- MVD | c.63C>G p.I21M | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV99964808; called by muse, mutect2
- MX2 | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as rs746032518, COSV58096026; called by muse, mutect2, varscan2
- MYCBP2 | c.8562G>C p.L2854F (on ENST00000357337; = p.L2892F on NM_015057.5) | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.351); catalogued as COSV62018755; called by muse, mutect2, varscan2
- MYCBP2 | c.405G>C p.K135N (on ENST00000357337; = p.K173N on NM_015057.5) | Missense Mutation (SNP) | VAF 73/159 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.149); catalogued as COSV100630618, COSV62018776; called by muse, mutect2, varscan2
- MYO1B | c.2650G>A p.E884K (on ENST00000304164; = p.E826K on NM_012223.5) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV58430859; called by muse, mutect2, varscan2
- MYO3A | c.2149G>C p.D717H | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56330557, COSV56335870; called by muse, mutect2, varscan2
- MYOM1 | c.3042G>A p.M1014I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs1350893428, COSV55291629, COSV55297314; called by muse, mutect2, varscan2
- NAA25 | c.2509C>G p.L837V | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV55704279; called by muse, mutect2, varscan2
- NCAPD2 | c.3348G>T p.M1116I | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV59699354; called by muse, mutect2, varscan2
- NCKAP1 | c.2653G>C p.D885H | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV62941127; called by muse, mutect2, varscan2
- NCOA5 | c.727G>C p.E243Q | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.692); catalogued as COSV51644320; called by muse, mutect2, varscan2
- NDC80 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | catalogued as rs1170337213, COSV55246667, COSV99859665; called by muse, mutect2, varscan2
- NDUFAF2 | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as rs772489808, COSV99410400; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEO1 | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV56068746; called by muse, mutect2, varscan2
- NFATC4 | c.1498G>A p.V500I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.131); catalogued as rs766194904, COSV51602336; called by muse, mutect2, varscan2
- NFKB2 | c.438G>C p.M146I | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.296); catalogued as rs377480135; called by muse, mutect2, varscan2
- NID2 | c.1355C>T p.S452L | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV53496334; called by muse, mutect2
- NIPBL | c.3463G>A p.D1155N | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV56951065; called by muse, mutect2
- NIPBL | c.5131G>C p.E1711Q | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.103); catalogued as COSV56951081; called by muse, mutect2, varscan2
- NKIRAS1 | c.321C>G p.F107L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV66248295; called by muse, mutect2, varscan2
- NLRC5 | c.1673C>G p.S558* | Nonsense Mutation (SNP) | VAF 7/58 reads (12%) | catalogued as COSV99347346; called by muse, varscan2
- NLRP14 | c.2127G>T p.L709F | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as COSV55067060; called by muse, mutect2, varscan2
- NPAS2 | c.1528G>C p.E510Q | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.562); catalogued as COSV59557690; called by muse, mutect2, varscan2
- NR5A2 | c.934G>C p.E312Q (on ENST00000367362 / NM_205860.3; = p.E266Q on NM_003822.5) | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV52650129; called by muse, mutect2, varscan2
- NRDC | c.2332C>G p.L778V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as rs12087917, COSV61404267; called by muse, mutect2, varscan2
- NRDE2 | c.3436G>A p.E1146K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62962319, COSV62964327; called by muse, mutect2, varscan2
- NSUN6 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.22); catalogued as rs1564853927, COSV66033168; called by muse, mutect2, varscan2
- NSUN7 | c.204C>G p.I68M | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV57273810; called by muse, mutect2, varscan2
- NUDT19 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs1237689689, COSV67959493; called by muse, mutect2
- NUP188 | c.3253C>T p.H1085Y | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV65362161; called by muse, mutect2, varscan2
- NUP214 | c.2452C>T p.H818Y | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.09); catalogued as COSV63909515; called by muse, mutect2, varscan2
- OCA2 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV62345546; called by muse, mutect2
- OIP5 | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.689); catalogued as COSV52973366; called by muse, mutect2
- OPA1 | c.1051G>A p.D351N (on ENST00000361510 / NM_130837.3; = p.D296N on NM_015560.3) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62480542; called by muse, mutect2, varscan2
- OR10A6 | c.841C>G p.L281V | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV59164885, COSV59165117; called by muse, mutect2, varscan2
- OR1A1 | c.312G>C p.M104I | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV58403404, COSV58403711; called by muse, mutect2, varscan2
- OR2A1 | c.405G>A p.M135I | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV101283384; called by mutect2, varscan2
- OR2T33 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58815358; called by muse, varscan2
- OR4K1 | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as COSV53460141; called by muse, mutect2, varscan2
- OR4P4 | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV58921958; called by muse, mutect2
- OR52D1 | c.264G>C p.L88F | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV59487527; called by muse, mutect2, varscan2
- ORC1 | c.1906C>G p.L636V | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100856583, COSV65363886; called by muse, mutect2, varscan2
- PAOX | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.217); catalogued as COSV53372362; called by muse, varscan2
- PAPPA | c.3868C>T p.H1290Y | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as COSV100074138; called by muse, mutect2, varscan2
- PAQR8 | c.484C>G p.H162D | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1465545452, COSV62442551; called by muse, mutect2, varscan2
- PAQR8 | c.865del p.L289Cfs*53 | Frame Shift Del (DEL) | VAF 11/66 reads (17%) | catalogued as COSV62442559; called by pindel, varscan2
- PCARE | c.3481G>A p.E1161K | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV100527680, COSV59053209; called by muse, mutect2, varscan2
- PCBP3 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68407894; called by muse, mutect2, varscan2
- PCNT | c.5548G>A p.E1850K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs375046076, COSV100855716; called by muse, mutect2, varscan2
- PCNX1 | c.3754G>C p.E1252Q | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.177); catalogued as COSV53094593; called by muse, mutect2, varscan2
- PCNX4 | c.1185G>C p.L395F (on ENST00000406854 / NM_001330177.2; = p.L161F on NM_022495.5) | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.861); catalogued as COSV58304119, COSV58309553; called by muse, mutect2
- PDE6A | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54924632; called by muse, mutect2
- PDZD7 | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760408643, COSV64646180; called by muse, mutect2, varscan2
- PGM2L1 | c.1819G>C p.E607Q | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV53346746; called by muse, mutect2, varscan2
- PIGO | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs773509452, COSV53053648; called by muse, mutect2, varscan2
- PIK3C2B | c.4037C>G p.S1346* | Nonsense Mutation (SNP) | VAF 15/77 reads (19%) | catalogued as COSV100916132; called by muse, mutect2, varscan2
- PIKFYVE | c.2446C>T p.Q816* | Nonsense Mutation (SNP) | VAF 28/99 reads (28%) | catalogued as COSV100010748; called by muse, mutect2, varscan2
- PIP5K1C | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV58951243; called by muse, mutect2, varscan2
- PIWIL4 | c.1352C>T p.S451L | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV54409325; called by muse, mutect2, varscan2
- PLAT | c.1010G>A p.G337E | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.122); catalogued as rs761915480, COSV54275590; called by muse, mutect2, varscan2
- PLEKHG1 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 7/83 reads (8%) | catalogued as COSV100651638, COSV62051656; called by muse, mutect2
- PLPP3 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs1349263606, COSV64839380; called by muse, mutect2, varscan2
- PMS1 | c.1277C>G p.S426C | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV59716427, COSV59721337; called by muse, mutect2, varscan2
- POLE2 | c.365C>T p.T122I | Missense Mutation (SNP) | VAF 9/251 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as rs897035611, COSV53559765; called by muse, mutect2
- POLG | c.3494C>T p.A1165V | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); catalogued as COSV51521554; called by muse, mutect2, varscan2
- POLK | c.474G>C p.K158N | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54035120; called by muse, mutect2, varscan2
- PPP1R15B | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65815782; called by muse, mutect2, varscan2
- PPP2R1A | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV59044321; called by muse, mutect2, varscan2
- PPP2R5E | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as rs373172813, COSV61741860, COSV61744329; called by muse, mutect2, varscan2
- PRAMEF1 | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 70/202 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV60009226; called by muse, mutect2, varscan2
- PRDM16 | c.1360G>T p.G454C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV54589975; called by muse, mutect2, varscan2
- PRDM7 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.883); catalogued as rs749367241, COSV68322249; called by muse, mutect2, varscan2
- PRKD1 | c.2065C>T p.Q689* | Nonsense Mutation (SNP) | VAF 40/86 reads (47%) | catalogued as COSV100120379, COSV59560634; called by muse, mutect2, varscan2
- PRKDC | c.8953G>A p.E2985K | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs1266172350, COSV100040699; called by muse, varscan2
- PROX2 | c.650C>G p.S217C | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as COSV71520054; called by muse, mutect2, varscan2
- PSAT1 | c.398-1G>C p.X133_splice | Splice Site (SNP) | VAF 37/189 reads (20%) | catalogued as COSV61302658; called by muse, mutect2, varscan2
- PSD3 | c.2202G>C p.E734D (on ENST00000440756; = p.E733D on NM_015310.4) | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV54071253; called by muse, mutect2, varscan2
- PSG7 | c.1139C>G p.S380C | Missense Mutation (SNP) | VAF 114/224 reads (51%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.819); catalogued as COSV68445115, COSV68446740; called by muse, mutect2, varscan2
- PSMD2 | c.2483G>A p.R828Q | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV59529676; called by muse, mutect2
- PYGM | c.2255C>A p.S752Y | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV51216919, COSV51232225; called by muse, mutect2, varscan2
- PYGO1 | c.1153G>C p.E385Q | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57347793; called by muse, mutect2, varscan2
- PZP | c.3175C>G p.R1059G | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54360379; called by muse, mutect2
- RABGAP1 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 8/236 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65380085; called by muse, mutect2
- RABGEF1 | c.42G>A p.M14I (on ENST00000439720 / NM_001287061.2; = p.M1? on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV53162269; called by muse, mutect2, varscan2
- RAD17 | c.1927C>A p.L643I (on ENST00000380774 / NM_133339.2; = p.L632I on NM_002873.1) | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.398); catalogued as COSV51457709; called by muse, mutect2, varscan2
- RAD23A | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 19/78 reads (24%) | catalogued as COSV100330727, COSV100330991; called by muse, mutect2, varscan2
- RAD51AP2 | c.3340C>A p.P1114T | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV101208345; called by muse, mutect2
- RAD54L2 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1471834971, COSV99621352; called by muse, mutect2, varscan2
- RALGDS | c.2560G>A p.D854N | Missense Mutation (SNP) | VAF 53/223 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as COSV64427220; called by muse, mutect2, varscan2
- RARS2 | c.375G>T p.K125N | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.614); catalogued as COSV65761039; called by muse, mutect2, varscan2
- RB1 | c.2447C>G p.S816* | Nonsense Mutation (SNP) | VAF 27/46 reads (59%) | catalogued as CM961238, COSV99924833; called by muse, mutect2, varscan2
- RBM17 | c.878C>G p.S293* | Nonsense Mutation (SNP) | VAF 7/120 reads (6%) | catalogued as COSV101159106; called by muse, mutect2
- RBM19 | c.1960C>G p.L654V | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55692051; called by muse, mutect2, varscan2
- RECQL | c.1491C>G p.I497M | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as COSV53708271, COSV53709580; called by muse, mutect2, varscan2
- RECQL5 | c.235C>T p.L79F | Missense Mutation (SNP) | VAF 49/263 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747076470, COSV53127872; called by muse, mutect2, varscan2
- RELN | c.1273G>C p.E425Q | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV59001815; called by muse, mutect2, varscan2
- RIOK2 | c.822G>A p.M274I | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV51612698; called by muse, mutect2, varscan2
- RIPOR3 | c.1925C>G p.S642* | Nonsense Mutation (SNP) | VAF 24/79 reads (30%) | catalogued as COSV99246506; called by muse, mutect2, varscan2
- RLF | c.4976C>T p.S1659L | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV65651807; called by muse, mutect2, varscan2
- RMC1 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 90/494 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV52570863; called by muse, mutect2, varscan2
- RMDN2 | c.577G>A p.E193K (on ENST00000354545 / NM_001322212.2; = p.E371K on NM_144713.5) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV52224941; called by muse, mutect2, varscan2
- RNF44 | c.982G>C p.D328H | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as COSV51269696; called by muse, mutect2, varscan2
- ROBO1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 18/74 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as COSV71965487, COSV71968596; called by muse, mutect2, varscan2
- RPS6KA5 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.025); catalogued as rs749352681, COSV100002603; called by muse, varscan2
- RSBN1L | c.314C>G p.S105C | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV100616055; called by muse, mutect2
- RTN4 | c.3490C>T p.H1164Y (on ENST00000337526 / NM_020532.5; = p.H171Y on NM_007008.3) | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58267665; called by muse, mutect2, varscan2
- RUFY2 | c.1627C>G p.L543V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV56259539; called by muse, mutect2, varscan2
- RYR1 | c.425-1G>T p.X142_splice | Splice Site (SNP) | VAF 10/40 reads (25%) | catalogued as COSV62097113; called by muse, mutect2, varscan2
- RYR3 | c.13577C>G p.S4526C (on ENST00000389232; = p.S4527C on NM_001036.6) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs749941098, COSV66788902; called by muse, mutect2, varscan2
- SAMD7 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1478521013, COSV59418676; called by muse, mutect2, varscan2
- SCN11A | c.3022G>C p.E1008Q | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as COSV56570273; called by muse, mutect2, varscan2
- SCNN1G | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.847); catalogued as COSV55597316, COSV55598867; called by muse, mutect2, varscan2
- SEC22A | c.149G>A p.R50K | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV59372130; called by muse, mutect2, varscan2
- SEC23IP | c.634C>T p.H212Y | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64831455; called by muse, mutect2
- SEMA3G | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.102); catalogued as COSV51595601, COSV51598144; called by muse, mutect2, varscan2
- SEMA6D | c.2951C>A p.P984Q (on ENST00000316364 / NM_153618.2; = p.P922Q on NM_020858.2) | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV60372910; called by muse, mutect2, varscan2
- SEPTIN11 | c.1043G>A p.R348K | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.029); catalogued as COSV99346387; called by muse, mutect2
- SEPTIN9 | c.1127G>A p.W376* (on ENST00000427177 / NM_001113491.2; = p.W358* on NM_006640.4) | Nonsense Mutation (SNP) | VAF 13/83 reads (16%) | catalogued as COSV100217997; called by muse, mutect2, varscan2
- SETD2 | c.6892C>G p.Q2298E | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as rs1372228141, COSV57437566; called by muse, mutect2, varscan2
- SETD5 | c.3170C>T p.P1057L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV100200649; called by muse, mutect2
- SETX | c.4870C>G p.L1624V | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0.24); catalogued as COSV56384968; called by muse, mutect2
- SF3A3 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV65955855; called by muse, mutect2, varscan2
- SFI1 | c.2576C>T p.T859M (on ENST00000400288 / NM_001007467.3; = p.T828M on NM_014775.4) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs766006241, COSV63475583; called by muse, mutect2, varscan2
- SFRP1 | c.501C>G p.I167M | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs766598576, COSV55172064, COSV99617363; called by muse, mutect2
- SGMS2 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1404081417, COSV62989276; called by muse, mutect2, varscan2
- SIGLEC10 | c.1861C>G p.R621G | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs763829345, COSV59481669; called by muse, mutect2, varscan2
- SIRT5 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV63079873, COSV63080493; called by muse, mutect2, varscan2
- SKIV2L | c.1667C>T p.S556F | Missense Mutation (SNP) | VAF 93/219 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.161); catalogued as rs1206899509, COSV64811575; called by muse, mutect2, varscan2
- SKIV2L | c.3188G>T p.R1063L | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV61713595; called by muse, mutect2, varscan2
- SLC26A8 | c.2149C>G p.L717V | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV62885027; called by muse, mutect2, varscan2
- SLC4A7 | c.1910G>C p.R637T | Missense Mutation (SNP) | VAF 11/363 reads (3%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.777); catalogued as COSV55397360; called by muse, mutect2
- SLC7A9 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV50085249; called by muse, mutect2, varscan2
- SLCO4A1 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.009); catalogued as rs749936587, COSV53890834; called by muse, mutect2, varscan2
- SLCO5A1 | c.817C>G p.L273V | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV52659307; called by muse, mutect2, varscan2
- SLITRK4 | c.1595C>T p.P532L | Missense Mutation (SNP) | VAF 61/75 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1556426695, COSV62023835; called by muse, mutect2, varscan2
- SLU7 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs1341621526, COSV51787439; called by muse, mutect2
- SLU7 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV51787671; called by muse, mutect2, varscan2
- SLU7 | c.913G>C p.D305H | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV51787686, COSV99775662; called by muse, mutect2
- SLX4 | c.5230C>T p.Q1744* | Nonsense Mutation (SNP) | VAF 16/38 reads (42%) | catalogued as COSV99568036; called by muse, mutect2, varscan2
- SMO | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs201246258, COSV50828849; called by mutect2, varscan2
- SNX5 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV66697814; called by muse, mutect2
- SOGA3 | c.2449G>A p.D817N | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs1342480576, COSV64106531; called by muse, mutect2, varscan2
- SOGA3 | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs757849083, COSV64106043; called by muse, mutect2, varscan2
- SP110 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV51250634; called by muse, mutect2, varscan2
- SPEN | c.4585C>T p.R1529C | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65363507; called by muse, mutect2
- SPG11 | c.667+1G>A p.X223_splice | Splice Site (SNP) | VAF 17/59 reads (29%) | catalogued as rs1435037360, COSV55994907; called by muse, mutect2, varscan2
- SPOCD1 | c.2792G>C p.R931T | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57096323; called by muse, mutect2, varscan2
- SPTLC3 | c.1177C>T p.H393Y | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.033); catalogued as rs941422250, COSV65465492; called by muse, mutect2
- SRRT | c.1658C>T p.S553L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV53815298; called by muse, mutect2, varscan2
- STK16 | c.835C>T p.Q279* | Nonsense Mutation (SNP) | VAF 6/72 reads (8%) | catalogued as COSV99850556; called by muse, mutect2
- STK17A | c.356C>G p.P119R | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV60046387, COSV60047100; called by muse, mutect2
- STK19 | c.378G>C p.K126N | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV61713611; called by muse, mutect2, varscan2
- STK19 | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61713615; called by muse, mutect2, varscan2
- SYNE1 | c.21074C>T p.S7025L (on ENST00000367255 / NM_182961.4; = p.S6954L on NM_033071.3) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54979416; called by muse, mutect2, varscan2
- SYS1 | c.165C>T p.I55= | Splice Region (SNP) | VAF 53/231 reads (23%) | catalogued as COSV54781767; called by muse, mutect2, varscan2
- SZT2 | c.9598G>A p.E3200K (on ENST00000634258 / NM_001365999.1; = p.E3143K on NM_015284.4) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65094543; called by muse, mutect2, varscan2
- TAPBPL | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); catalogued as rs770316205, COSV56946863; called by muse, mutect2, varscan2
- TAS1R2 | c.1935C>G p.I645M | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV64744947; called by muse, mutect2, varscan2
- TAS2R9 | c.792G>C p.L264F | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.678); catalogued as COSV53688195, COSV53688635; called by muse, mutect2
- TASOR | c.1408C>A p.L470I (on ENST00000355628 / NM_001365636.2; = p.L74I on NM_015224.3) | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV62927783; called by muse, mutect2, varscan2
- TBC1D12 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.349); catalogued as rs1421284638, COSV56554177; called by muse, mutect2, varscan2
- TBC1D8B | c.2542C>T p.H848Y | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.085); catalogued as COSV52178794; called by muse, mutect2, varscan2
- TBC1D9 | c.2065G>C p.E689Q | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.525); catalogued as COSV71307483; called by muse, mutect2, varscan2
- TCAIM | c.686C>G p.S229* | Nonsense Mutation (SNP) | VAF 14/183 reads (8%) | catalogued as COSV100703271; called by muse, mutect2
- TCOF1 | c.1938G>C p.K646N (on ENST00000377797 / NM_001135243.1; = p.K569N on NM_000356.4) | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.675); catalogued as COSV60348364; called by muse, mutect2, varscan2
- TEF | c.407C>G p.S136C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV99841931; called by muse, mutect2
- TEKT5 | c.988C>A p.Q330K | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV51588847; called by muse, mutect2, varscan2
- TENT5C | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs780173405, COSV65616382; called by muse, mutect2, varscan2
- TEX15 | c.5150G>A p.R1717Q (on ENST00000256246; = p.R2100Q on NM_001350162.2) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774803241, COSV56346351; called by muse, mutect2, varscan2
- TEX15 | c.89C>T p.S30F (on ENST00000256246; = p.S413F on NM_001350162.2) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV56346365, COSV56349511; called by muse, mutect2
- TFDP2 | c.1212C>A p.F404L (on ENST00000489671 / NM_001178139.2; = p.F344L on NM_006286.5) | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs1409876723, COSV57706560, COSV57707694; called by muse, mutect2, varscan2
- THBS3 | c.2803C>T p.R935* | Nonsense Mutation (SNP) | VAF 79/136 reads (58%) | catalogued as COSV100104335; called by muse, mutect2, varscan2
- THRB | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); catalogued as COSV54980196; called by muse, mutect2, varscan2
- TIGD2 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV57647776; called by muse, mutect2, varscan2
- TM9SF3 | c.661-1G>C p.X221_splice | Splice Site (SNP) | VAF 15/48 reads (31%) | catalogued as COSV64457406; called by muse, mutect2, varscan2
- TMCO3 | c.146G>A p.W49* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as rs778298719, COSV100952332; called by muse, mutect2, varscan2
- TMEM62 | c.1055C>G p.S352C | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV53041084, COSV53043100; called by muse, mutect2, varscan2
- TMEM68 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.764); catalogued as rs776952992, COSV58170936; called by muse, mutect2, varscan2
- TMEM9 | c.76G>C p.D26H | Missense Mutation (SNP) | VAF 15/171 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV66243841; called by muse, mutect2
- TMTC2 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV58268501; called by muse, mutect2, varscan2
- TPSD1 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs772451768, COSV52975607; called by mutect2, varscan2
- TRAPPC4 | c.85G>C p.E29Q | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57722787; called by muse, mutect2, varscan2
- TRAPPC5 | c.345C>G p.F115L | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV58040003; called by muse, mutect2
- TRDN | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); catalogued as rs1221151600, COSV100522026; called by muse, mutect2, varscan2
- TREH | c.1371G>T p.K457N | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs1555144333, COSV50621107; called by muse, mutect2, varscan2
- TREML1 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV64191174; called by muse, mutect2, varscan2
- TRIM23 | c.142C>G p.L48V | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.12); catalogued as COSV51551358; called by muse, mutect2, varscan2
- TRIM45 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV56713570; called by muse, varscan2
- TRPM6 | c.2844C>A p.F948L | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as rs13290391; called by muse, mutect2
- TRRAP | c.1986C>G p.I662M | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as rs781803289, COSV62844207, COSV62847805; called by muse, mutect2, varscan2
- TRRAP | c.10057G>C p.E3353Q (on ENST00000359863 / NM_001244580.1; = p.E3324Q on NM_003496.3) | Missense Mutation (SNP) | VAF 89/238 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV62842871; called by muse, mutect2, varscan2
- TRRAP | c.11359G>C p.E3787Q (on ENST00000359863 / NM_001244580.1; = p.E3758Q on NM_003496.3) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.424); catalogued as COSV62816117; called by muse, mutect2, varscan2
- TSPAN16 | c.600G>C p.Q200H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV57442238; called by muse, mutect2, varscan2
- TSR1 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs763903564, COSV56784951; called by muse, mutect2, varscan2
- TSR1 | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as COSV52157909; called by muse, mutect2, varscan2
- TTC14 | c.173G>C p.R58T | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.081); catalogued as COSV56011065; called by muse, mutect2, varscan2
- TTLL7 | c.1816C>T p.R606W | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs143330409; called by mutect2, varscan2
- TULP2 | c.974G>A p.R325K | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs199974267, COSV55477978; called by muse, mutect2, varscan2
- TULP4 | c.2595G>C p.L865F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.3); catalogued as COSV100893503; called by muse, mutect2
- UBA6 | c.2548G>C p.E850Q | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100451743, COSV59177029; called by muse, mutect2, varscan2
- UBE4A | c.2643G>C p.L881F (on ENST00000252108 / NM_001204077.2; = p.L888F on NM_004788.4) | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.857); catalogued as COSV52804157; called by muse, mutect2, varscan2
- UFD1 | c.884G>C p.G295A | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54251335; called by muse, mutect2, varscan2
- UGGT2 | c.1786C>T p.H596Y | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV65074732; called by muse, mutect2, varscan2
- UNC5C | c.2284C>T p.Q762* | Nonsense Mutation (SNP) | VAF 22/86 reads (26%) | catalogued as COSV101497908; called by muse, mutect2, varscan2
- USP37 | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.438); catalogued as COSV51443357; called by muse, mutect2, varscan2
- USP6 | c.3085G>A p.E1029K | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.576); catalogued as rs149187210; called by muse, mutect2, varscan2
- VCAN | c.5587G>A p.E1863K | Missense Mutation (SNP) | VAF 78/149 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775843686, COSV54102497; called by muse, mutect2, varscan2
- VEPH1 | c.1274C>G p.S425C | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV62876470; called by muse, mutect2, varscan2
- VSTM2A | c.665C>A p.S222Y | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.974); catalogued as COSV68289811; called by muse, mutect2, varscan2
- WDR3 | c.2728G>A p.E910K | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs768211246, COSV60458697; called by muse, mutect2, varscan2
- WDR47 | c.2638C>T p.P880S (on ENST00000369962 / NM_001142551.2; = p.P881S on NM_014969.5) | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV63058030; called by muse, mutect2, varscan2
- WDR48 | c.1282-1G>A p.X428_splice | Splice Site (SNP) | VAF 12/57 reads (21%) | catalogued as COSV56531933; called by muse, mutect2, varscan2
- WIPF2 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as rs1179411815, COSV100063597; called by muse, mutect2
- WNK1 | c.2192C>T p.S731L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV60029657; called by muse, mutect2, varscan2
- WNK3 | c.4690G>A p.E1564K | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.156); catalogued as COSV63613983; called by muse, mutect2, varscan2
- XPOT | c.641C>G p.S214C | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60345346; called by muse, mutect2
- YY1AP1 | c.2077G>A p.D693N (on ENST00000295566 / NM_139118.2; = p.D636N on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs146837303; called by muse, mutect2, varscan2
- YY1AP1 | c.1367C>T p.S456L (on ENST00000295566 / NM_139118.2; = p.S399L on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.838); catalogued as COSV55121189, COSV99804676; called by muse, mutect2
- ZACN | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.96); catalogued as COSV58036106; called by muse, mutect2
- ZFYVE9 | c.898C>G p.P300A | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs567617178, COSV55093809; called by muse, mutect2, varscan2
- ZKSCAN7 | c.2027C>G p.S676C | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV56272800; called by muse, mutect2, varscan2
- ZMYM4 | c.2234C>T p.S745L | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV58910433; called by muse, mutect2
- ZNF133 | c.1520C>G p.S507* (on ENST00000316358 / NM_001352454.2; = p.S506* on NM_003434.7 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 23/53 reads (43%) | catalogued as COSV100315512; called by muse, mutect2, varscan2
- ZNF142 | c.4948C>T p.R1650C (on ENST00000411696 / NM_001379660.1; = p.R1450C on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.178); catalogued as rs770446898, COSV68743703; called by muse, mutect2, varscan2
- ZNF221 | c.1021G>C p.D341H | Missense Mutation (SNP) | VAF 64/120 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV52109365; called by muse, mutect2, varscan2
- ZNF23 | c.1324C>T p.H442Y | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61840935; called by muse, mutect2, varscan2
- ZNF263 | c.439C>G p.L147V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as rs747562430, COSV54595721, COSV54596495; called by muse, mutect2, varscan2
- ZNF274 | c.679G>A p.E227K (on ENST00000610905; = p.E122K on NM_016324.3) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV58764368; called by muse, mutect2, varscan2
- ZNF335 | c.3736G>A p.E1246K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV59817758; called by muse, mutect2, varscan2
- ZNF433 | c.1967G>A p.R656K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.129); catalogued as COSV61399108; called by mutect2, varscan2
- ZNF436 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0.058); catalogued as COSV58358531; called by muse, mutect2, varscan2
- ZNF527 | c.105G>C p.Q35H | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62233460, COSV62237952; called by muse, mutect2
- ZNF556 | c.312G>C p.L104F | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as rs374875450; called by muse, mutect2, varscan2
- ZNF570 | c.1229G>C p.G410A | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57579114; called by muse, mutect2
- ZNF594 | c.996C>A p.F332L | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as rs1202060308, COSV68385256; called by muse, mutect2, varscan2
- ZNF608 | c.2713G>C p.E905Q | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV60437679; called by muse, mutect2, varscan2
- ZNF660 | c.684C>G p.I228M | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.295); catalogued as COSV59549046; called by muse, mutect2, varscan2
- ZNF74 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 8/67 reads (12%) | catalogued as COSV100677488; called by muse, mutect2, varscan2
- ZNF75D | c.642G>C p.Q214H | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.712); catalogued as rs782075742, COSV66132713; called by muse, mutect2, varscan2
- ZNF773 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56588500; called by muse, mutect2, varscan2
- ZNF780B | c.2125C>T p.H709Y | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as COSV55464154, COSV99665176; called by muse, mutect2
- ZNF804A | c.1298G>C p.R433T | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV56448346; called by muse, mutect2, varscan2
- ZSCAN22 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as COSV61639105; called by muse, mutect2, varscan2
- ZW10 | c.2258C>T p.S753F | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV52316524; called by muse, mutect2, varscan2
- ZZEF1 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.299); catalogued as COSV67557435; called by muse, mutect2
- AHCTF1 | c.2712dup p.V905Sfs*5 (on ENST00000366508; = p.V879Sfs*5 on NM_015446.5) | Frame Shift Ins (INS) | VAF 27/65 reads (42%) | called by mutect2, pindel, varscan2
- CECR2 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- DBN1 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- IGHE | c.1057G>C p.E353Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PPP2R2B | c.67G>A p.E23K (on ENST00000394409; = p.E89K on NM_181674.2) | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- RADIL | c.2951C>G p.S984C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.062); called by muse, mutect2
- SYNRG | c.1790C>G p.S597* | Nonsense Mutation (SNP) | VAF 19/120 reads (16%) | called by muse, mutect2, varscan2
- ZNF140 | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ABCB8 | c.384G>A p.V128= (on ENST00000297504 / NM_001282291.2; = p.V111= on NM_007188.5) | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs1219032230, COSV52504519; called by muse, mutect2, varscan2
- AC007040.2 | c.291C>T p.F97= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV55592279; called by muse, mutect2, varscan2
- ACLY | c.2337G>A p.L779= | Silent (SNP) | VAF 6/87 reads (7%) | catalogued as rs1555626658, COSV61250672; called by muse, mutect2
- ACTA2 | c.216G>A p.P72= | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as rs181255627; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADGRD1 | c.1590G>A p.T530= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs1438137558, COSV55445237; called by muse, mutect2, varscan2
- ADGRV1 | c.17860C>T p.L5954= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV67985041; called by muse, mutect2, varscan2
- ADIG | c.96C>T p.I32= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV53437617; called by muse, mutect2, varscan2
- ANKIB1 | c.1338C>G p.L446= | Silent (SNP) | VAF 30/180 reads (17%) | catalogued as COSV56061325, COSV56061993; called by muse, mutect2, varscan2
- ARFGEF1 | c.4528C>T p.L1510= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as COSV51604385, COSV51608594; called by muse, mutect2, varscan2
- ARHGAP27 | c.2214G>C p.L738= (on ENST00000428638 / NM_001282290.1; = p.L397= on NM_199282.3) | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV65357769; called by muse, mutect2, varscan2
- ARHGAP35 | c.3942G>A p.V1314= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV68331171; called by muse, mutect2, varscan2
- ASXL2 | c.462C>T p.V154= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs573025949, COSV55458662; called by muse, mutect2, varscan2
- ATE1 | c.1050C>T p.I350= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV56436354; called by muse, mutect2, varscan2
- ATP6V1H | c.495C>T p.F165= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV62218261; called by muse, mutect2, varscan2
- BCL6 | c.1602G>A p.K534= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV51652040; called by muse, mutect2, varscan2
- BMP2 | c.915C>T p.F305= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV66577838; called by muse, mutect2, varscan2
- BTRC | c.1287C>T p.V429= (on ENST00000370187 / NM_033637.4; = p.V393= on NM_003939.5) | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV64579530; called by muse, mutect2, varscan2
- CA10 | c.714G>A p.S238= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as rs374650198; called by muse, mutect2, varscan2
- CACNA1H | c.4035G>A p.V1345= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs747258959, COSV100672603; ClinVar: likely benign; called by muse, varscan2
- CADPS2 | c.3765G>A p.L1255= | Silent (SNP) | VAF 27/161 reads (17%) | catalogued as COSV57363351; called by muse, mutect2, varscan2
- CAPN5 | c.48G>A p.L16= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV53687810; called by muse, mutect2, varscan2
- CARMIL3 | c.1959G>A p.Q653= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as rs61732659, COSV57726338; called by muse, mutect2, varscan2
- CASKIN1 | c.504C>A p.L168= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV58871316, COSV58874410; called by muse, mutect2, varscan2
- CASQ1 | c.642C>T p.F214= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as rs777919700, COSV63624148; called by muse, mutect2, varscan2
- CCNB2 | c.426C>T p.L142= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV55595428; called by muse, mutect2, varscan2
- CCNJL | c.1008C>T p.L336= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs750898193, COSV57444734; called by mutect2, varscan2
- CCT7 | c.957G>A p.L319= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs775077783, COSV57822089; called by muse, varscan2
- CDH4 | c.801C>T p.V267= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as COSV64654441; called by muse, mutect2, varscan2
- CENPV | c.528G>A p.K176= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as COSV55333309; called by muse, mutect2, varscan2
- CEP70 | c.423G>A p.Q141= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV53875661; called by muse, mutect2, varscan2
- CGN | c.1407G>C p.L469= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV99642350; called by muse, mutect2
- CHAF1A | c.1119G>A p.K373= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1418908759; called by muse, mutect2
- CHCHD1 | c.117G>A p.E39= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV65708335; called by muse, mutect2, varscan2
- CHRM3 | c.1387C>T p.L463= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV55088977, COSV55094278; called by muse, mutect2, varscan2
- CHST12 | c.489C>T p.H163= | Silent (SNP) | VAF 49/141 reads (35%) | catalogued as rs774969501, COSV51675037; called by muse, mutect2, varscan2
- CIAO3 | c.234C>T p.I78= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as COSV52402207; called by muse, mutect2, varscan2
- CIC | c.3372C>T p.T1124= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as rs758814892, COSV50569869; called by muse, mutect2, varscan2
- CIP2A | c.2379G>A p.Q793= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as rs1422594827, COSV55418674; called by muse, mutect2
- CLIP1 | c.3882C>G p.L1294= (on ENST00000620786 / NM_001247997.1; = p.L1283= on NM_002956.2) | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV56801676; called by muse, mutect2, varscan2
- CLUAP1 | c.129G>A p.V43= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV58893603; called by mutect2, varscan2
- COA7 | c.39C>G p.V13= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV65299500; called by muse, mutect2, varscan2
- COL9A1 | c.1113C>T p.L371= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs1298969461, COSV57882100; called by muse, mutect2, varscan2
- COX10 | c.765G>A p.V255= | Silent (SNP) | VAF 40/103 reads (39%) | catalogued as COSV55404990; called by muse, mutect2, varscan2
- CTSD | c.1146C>T p.L382= | Silent (SNP) | VAF 34/64 reads (53%) | catalogued as COSV52587212, COSV52588233; called by muse, mutect2, varscan2
- CTTNBP2NL | c.690G>A p.Q230= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs1402551258, COSV54744410, COSV54744469; called by muse, mutect2, varscan2
- CWC27 | c.726C>T p.L242= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV101126501; called by muse, mutect2
- CYP2C8 | c.936C>T p.L312= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as rs200154618, COSV64877108; called by muse, mutect2, varscan2
- CYRIA | c.912C>T p.F304= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV62865127; called by muse, mutect2, varscan2
- DAGLA | c.1680C>G p.T560= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs762001746, COSV57195998, COSV99944764; called by muse, mutect2, varscan2
- DGKG | c.2025G>A p.K675= | Silent (SNP) | VAF 5/93 reads (5%) | catalogued as rs1282942490, COSV53963763, COSV99403344; called by muse, mutect2
- DHX16 | c.1254C>G p.L418= | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as COSV64563923; called by muse, mutect2
- DNAH11 | c.8556C>G p.L2852= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV60955537, COSV60958982; called by muse, mutect2, varscan2
- DNAH7 | c.9054T>C p.P3018= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV56764628; called by muse, mutect2, varscan2
- E4F1 | c.12G>A p.A4= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs564228065, COSV100065771; called by muse, varscan2
- EIF4G3 | c.1149G>A p.L383= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV51681865; called by muse, mutect2, varscan2
- ENTPD7 | c.609C>G p.L203= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV65112285; called by muse, mutect2, varscan2
- EPN2 | c.891C>T p.L297= | Silent (SNP) | VAF 32/107 reads (30%) | catalogued as COSV59061190; called by muse, mutect2, varscan2
- ERBB2 | c.1255C>T p.L419= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV54070421; called by muse, mutect2, varscan2
- ERN2 | c.1863G>A p.L621= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1397248036, COSV55622118; called by muse, mutect2, varscan2
- ESRP1 | c.1737G>A p.L579= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV64409042, COSV64409702; called by muse, mutect2, varscan2
- FADS3 | c.801C>T p.F267= | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as COSV53878464, COSV53880874; called by muse, mutect2, varscan2
- FADS3 | c.723C>T p.F241= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV53877663; called by mutect2, varscan2
- FBN3 | c.8136G>A p.L2712= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99495161; called by muse, mutect2
- FDXR | c.660G>A p.V220= (on ENST00000293195 / NM_024417.5; = p.V226= on NM_004110.6) | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV53121953; called by muse, mutect2, varscan2
- FEM1A | c.993G>A p.Q331= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as COSV54163812; called by muse, mutect2, varscan2
- FFAR1 | c.300G>A p.L100= | Silent (SNP) | VAF 16/23 reads (70%) | catalogued as COSV50052684; called by muse, mutect2, varscan2
- FGD3 | c.1239C>T p.F413= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV61597277; called by muse, mutect2, varscan2
- FKBP1B | c.213G>A p.Q71= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV51980817; called by muse, mutect2, varscan2
- FLG | c.8646G>A p.R2882= | Silent (SNP) | VAF 88/599 reads (15%) | catalogued as rs144057082, COSV64242505; called by muse, mutect2, varscan2
- FUBP3 | c.951C>T p.I317= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV60514202; called by muse, mutect2, varscan2
- GABRR3 | c.177G>A p.Q59= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV72084100; called by muse, mutect2, varscan2
- GALK2 | c.453C>G p.V151= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV59101409; called by muse, mutect2, varscan2
- GIMAP8 | c.1671G>A p.T557= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs557029400, COSV56230717; called by muse, mutect2, varscan2
- GOLGA1 | c.2061G>A p.L687= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV52346781; called by muse, mutect2, varscan2
- H2BC10 | c.141G>A p.K47= | Silent (SNP) | VAF 134/329 reads (41%) | catalogued as rs753538230, COSV59952990; called by muse, mutect2, varscan2
- HTR2B | c.627G>A p.L209= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV51449728; called by muse, mutect2, varscan2
- IGHV1-58 | c.210C>T p.I70= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as rs947808103; called by muse, mutect2
- IGSF9B | c.1779C>T p.F593= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs1450137181, COSV58072247; called by muse, mutect2, varscan2
- IKZF1 | c.786C>T p.L262= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as rs150385329; called by mutect2, varscan2
- ITGAX | c.3399C>T p.F1133= | Silent (SNP) | VAF 30/107 reads (28%) | catalogued as COSV51645613; called by muse, mutect2, varscan2
- ITPR3 | c.5629C>T p.L1877= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV65409102; called by muse, mutect2, varscan2
- ITSN2 | c.3234G>A p.Q1078= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV61947171; called by muse, mutect2, varscan2
- KCTD19 | c.2202G>A p.Q734= | Silent (SNP) | VAF 7/84 reads (8%) | catalogued as COSV58572878; called by muse, mutect2
- KHDRBS3 | c.339G>A p.R113= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs1477293791, COSV63418448; called by muse, mutect2, varscan2
- KIAA1522 | c.1713C>G p.L571= (on ENST00000373480 / NM_001198972.2; = p.L630= on NM_020888.3) | Silent (SNP) | VAF 55/90 reads (61%) | catalogued as COSV53864489, COSV99614088; called by muse, mutect2, varscan2
- KIF5C | c.2496G>A p.Q832= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV68481234; called by muse, mutect2, varscan2
- KLHL36 | c.1335C>T p.F445= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as rs1230326142, COSV50719021; called by muse, mutect2, varscan2
- KY | c.1569G>A p.L523= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as COSV71016384; called by muse, mutect2, varscan2
- LAMB4 | c.3162G>A p.P1054= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs576296424, COSV52718922; called by muse, mutect2, varscan2
- LMTK3 | c.834G>A p.L278= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV99540512; called by muse, mutect2
- LRIG1 | c.1593G>A p.K531= | Silent (SNP) | VAF 19/259 reads (7%) | catalogued as COSV56239948; called by muse, mutect2
- MADD | c.3060C>T p.L1020= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV60624025; called by muse, mutect2, varscan2
- MAP2K2 | c.657C>A p.L219= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV99502368; called by muse, mutect2
- MAP3K5 | c.1311C>T p.V437= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as COSV100752739, COSV62889146; called by muse, mutect2, varscan2
- MFSD6L | c.1236G>A p.L412= | Silent (SNP) | VAF 60/139 reads (43%) | catalogued as COSV61003132; called by muse, mutect2, varscan2
- MGAT5 | c.1671G>A p.L557= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV99924508; called by muse, mutect2
- MINDY1 | c.438C>T p.L146= | Silent (SNP) | VAF 37/120 reads (31%) | catalogued as COSV56498804; called by muse, mutect2, varscan2
- MLH1 | c.1968C>T p.F656= | Silent (SNP) | VAF 34/174 reads (20%) | catalogued as CD054968, COSV51617949; called by muse, mutect2, varscan2
- MTO1 | c.210C>T p.D70= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs138494495; ClinVar: likely benign; called by muse, mutect2
- MYCBPAP | c.2436G>A p.V812= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV52139848; called by muse, mutect2, varscan2
- NCF1 | c.375C>G p.L125= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV56876394; called by mutect2, varscan2
- NCOA4 | c.555C>T p.I185= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs782624318; called by muse, mutect2, varscan2
- NCOR1 | c.6414G>A p.E2138= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs1464675338, COSV51974482; called by muse, mutect2, varscan2
- NSD2 | c.1065C>G p.L355= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV56390667; called by muse, mutect2, varscan2
- NTNG1 | c.993G>A p.K331= | Silent (SNP) | VAF 30/104 reads (29%) | catalogued as rs767224165, COSV53971070; called by muse, mutect2, varscan2
- NTRK1 | c.981C>T p.F327= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV62325569; called by muse, mutect2, varscan2
- NUMA1 | c.624C>T p.I208= | Silent (SNP) | VAF 60/104 reads (58%) | catalogued as rs976400209, COSV61185554; called by muse, mutect2, varscan2
- NXPE1 | c.1239G>C p.L413= (on ENST00000424269; = p.L271= on NM_152315.5) | Silent (SNP) | VAF 6/79 reads (8%) | catalogued as COSV52629220; called by muse, mutect2
- OR10C1 | c.621C>A p.L207= (on ENST00000622521; = p.L205= on NM_013941.3) | Silent (SNP) | VAF 16/184 reads (9%) | catalogued as COSV65822832; called by muse, mutect2
- OR11A1 | c.603C>T p.L201= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV65820969; called by muse, varscan2
- OR2AE1 | c.900G>C p.L300= | Silent (SNP) | VAF 37/154 reads (24%) | catalogued as COSV60390224; called by muse, mutect2, varscan2
- OR52N2 | c.150C>T p.L50= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as COSV57676822; called by muse, mutect2
- PACC1 | c.720C>A p.V240= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV54787867; called by muse, mutect2
- PEMT | c.60C>T p.I20= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV55131373; called by muse, mutect2, varscan2
- PGA3 | c.69C>T p.I23= | Silent (SNP) | VAF 14/17 reads (82%) | called by mutect2, varscan2
- PGM1 | c.1632G>A p.L544= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as COSV64300508; called by muse, mutect2, varscan2
- PIGG | c.2316G>A p.T772= (on ENST00000453061 / NM_001127178.3; = p.T764= on NM_017733.4) | Silent (SNP) | VAF 22/127 reads (17%) | catalogued as rs199894962, COSV56316121, COSV56317683; called by muse, mutect2, varscan2
- PKD1 | c.8934C>T p.F2978= | Silent (SNP) | VAF 31/48 reads (65%) | catalogued as rs1413650163, COSV51916132; called by muse, mutect2, varscan2
- PKDREJ | c.5187C>G p.V1729= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV53549255; called by muse, mutect2, varscan2
- PRMT1 | c.306C>T p.L102= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV101212269; called by muse, mutect2, varscan2
- PTPRT | c.1614G>A p.Q538= | Silent (SNP) | VAF 7/77 reads (9%) | catalogued as COSV61980986, COSV62015076; called by muse, mutect2
- PURG | c.393G>C p.L131= | Silent (SNP) | VAF 40/92 reads (43%) | catalogued as COSV53295591, COSV53296220; called by muse, mutect2, varscan2
- RAD51AP2 | c.321C>G p.L107= | Silent (SNP) | VAF 29/108 reads (27%) | catalogued as COSV67588049; called by muse, mutect2, varscan2
- RASGRP2 | c.1830_*2del | Silent (DEL) | VAF 14/87 reads (16%) | called by mutect2, pindel, varscan2
- RASL12 | c.780G>A p.L260= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV99584965; called by muse, mutect2
- RFPL2 | c.609C>T p.D203= | Silent (SNP) | VAF 42/85 reads (49%) | catalogued as rs753078382, COSV50710845; called by muse, mutect2, varscan2
- RFXANK | c.457C>T p.L153= | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as COSV57393662; called by muse, mutect2, varscan2
- RICTOR | c.1497G>A p.Q499= | Silent (SNP) | VAF 26/158 reads (16%) | catalogued as COSV57121931, COSV57122456; called by muse, mutect2, varscan2
- ROR2 | c.834C>T p.L278= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV65219067; called by muse, mutect2, varscan2
- RRP12 | c.1920C>T p.F640= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs1465012693, COSV59667442; called by muse, mutect2, varscan2
- SBF2 | c.1224C>T p.L408= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV56298968, COSV99812672; called by muse, mutect2, varscan2
- SCN11A | c.4632C>T p.L1544= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV56570269; called by muse, mutect2, varscan2
- SCRT1 | c.30C>G p.V10= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100146462; called by muse, mutect2
- SELENOI | c.1066C>T p.L356= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV99564452; called by muse, mutect2
- SELENOO | c.1974C>T p.L658= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as rs1052827, COSV50545596; called by muse, mutect2, varscan2
- SH3GL2 | c.294C>G p.L98= | Silent (SNP) | VAF 35/58 reads (60%) | catalogued as COSV66050401; called by muse, mutect2, varscan2
- SKIV2L | c.2418C>T p.V806= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs766365855, COSV61713590; called by muse, mutect2, varscan2
- SLC37A1 | c.1062C>T p.I354= | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as rs1468304901, COSV61402379; called by muse, mutect2, varscan2
- SLFN5 | c.2382C>T p.F794= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as rs982276704, COSV55481175; called by muse, mutect2, varscan2
- SLU7 | c.789G>A p.R263= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV51787701; called by muse, mutect2, varscan2
- SMYD4 | c.519C>T p.F173= | Silent (SNP) | VAF 15/178 reads (8%) | catalogued as COSV59711617; called by muse, mutect2
- SOX9 | c.1206G>C p.L402= | Silent (SNP) | VAF 11/100 reads (11%) | called by muse, mutect2
- SPNS3 | c.498G>A p.V166= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV61070034; called by muse, mutect2, varscan2
- SPPL2B | c.1242C>T p.F414= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV101194639; called by muse, mutect2, varscan2
- SRCAP | c.2769C>T p.F923= | Silent (SNP) | VAF 94/302 reads (31%) | catalogued as rs1485801425, COSV52672522; called by muse, varscan2
- SRGAP1 | c.312G>A p.L104= | Silent (SNP) | VAF 6/67 reads (9%) | catalogued as COSV61897954; called by muse, mutect2
- STAG2 | c.354C>T p.I118= | Silent (SNP) | VAF 8/93 reads (9%) | catalogued as COSV54353949, COSV54358271; called by muse, mutect2
- SUGP1 | c.351C>G p.P117= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV55921678; called by muse, mutect2
- TAS1R2 | c.2229C>T p.F743= | Silent (SNP) | VAF 30/41 reads (73%) | catalogued as COSV64744872; called by muse, mutect2, varscan2
- TAS2R50 | c.75C>G p.G25= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV67855806; called by muse, mutect2, varscan2
- TCEANC2 | c.393G>A p.L131= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as rs1470194316, COSV52369932; called by muse, mutect2, varscan2
- TENM1 | c.5307C>T p.I1769= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as rs766658845, COSV64431702; called by muse, mutect2, varscan2
- TENM2 | c.6477G>A p.R2159= (on ENST00000518659 / NM_001122679.2; = p.R1920= on NM_001080428.3) | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as COSV69130048; called by muse, mutect2, varscan2
- TGFB2 | c.447C>T p.F149= | Silent (SNP) | VAF 20/185 reads (11%) | catalogued as COSV65109271, COSV65109302; called by muse, mutect2, varscan2
- TIAM1 | c.2292C>T p.F764= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs1256223720, COSV54550743; called by muse, mutect2, varscan2
- TICRR | c.2859G>A p.K953= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV51541360; called by muse, mutect2, varscan2
- TLN2 | c.3429G>A p.S1143= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs751572891, COSV60889694; called by muse, mutect2, varscan2
- TMC1 | c.1620C>T p.L540= | Silent (SNP) | VAF 14/192 reads (7%) | catalogued as rs145772877; called by muse, mutect2
- TMC3 | c.225G>A p.L75= | Silent (SNP) | VAF 28/165 reads (17%) | catalogued as rs773833840, COSV63923145; called by muse, mutect2, varscan2
- TNFRSF10D | c.720C>T p.L240= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV57035699; called by muse, mutect2, varscan2
- TRAPPC1 | c.126C>G p.L42= | Silent (SNP) | VAF 5/69 reads (7%) | catalogued as COSV58050235; called by muse, mutect2
- TRIM45 | c.168G>A p.L56= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as COSV56713579; called by muse, varscan2
- TRMT2B | c.843C>T p.F281= | Silent (SNP) | VAF 27/33 reads (82%) | catalogued as COSV58619523; called by muse, mutect2, varscan2
- UGGT1 | c.1875G>A p.Q625= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as rs752145530, COSV52135696; called by muse, mutect2, varscan2
- UGT1A8 | c.54G>C p.L18= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV65077047, COSV65078211; called by muse, mutect2, varscan2
- USHBP1 | c.534G>A p.E178= | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as COSV53103562; called by muse, mutect2, varscan2
- VHL | c.489C>T p.L163= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV56550040; called by muse, mutect2, varscan2
- VIPR1 | c.867C>A p.I289= | Silent (SNP) | VAF 14/113 reads (12%) | catalogued as COSV100285821, COSV57297387; called by muse, mutect2, varscan2
- VN1R5 | c.468C>T p.L156= | Silent (SNP) | VAF 6/119 reads (5%) | catalogued as rs1022638553; called by muse, mutect2
- WDR64 | c.2622C>A p.I874= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV63795924; called by muse, mutect2, varscan2
- ZACN | c.483C>T p.L161= | Silent (SNP) | VAF 9/96 reads (9%) | catalogued as COSV58036099; called by muse, mutect2, varscan2
- ZBTB46 | c.372C>T p.F124= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV55510003; called by muse, mutect2, varscan2
- ZHX1 | c.451C>T p.L151= | Silent (SNP) | VAF 26/115 reads (23%) | catalogued as rs1451335797, COSV52876469; called by muse, mutect2, varscan2
- ZMYM3 | c.2245C>T p.L749= | Silent (SNP) | VAF 18/25 reads (72%) | catalogued as COSV58737827; called by muse, mutect2, varscan2
- ZNF107 | c.387G>A p.V129= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV61328588; called by muse, mutect2, varscan2
- ZNF33A | c.2289C>G p.L763= (on ENST00000458705 / NM_006974.3; = p.L764= on NM_006954.2) | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV56724966, COSV56725167; called by muse, mutect2, varscan2
- ZNF547 | c.1098C>T p.H366= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs1428420831, COSV56580429; called by muse, mutect2, varscan2
- ZNF780B | c.1830G>A p.E610= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV55464176; called by muse, mutect2, varscan2
- CALCR | c.51+2951G>T | Intron (SNP) | VAF 26/115 reads (23%) | catalogued as COSV100810552; called by muse, mutect2, varscan2
- CDH2 | c.173-22592G>C | Intron (SNP) | VAF 63/154 reads (41%) | catalogued as rs772049531, COSV52280151, COSV52288351; called by muse, mutect2, varscan2
- DDX41 | c.*633C>T | 3'UTR (SNP) | VAF 13/56 reads (23%) | catalogued as rs776477683, COSV57252256; called by muse, mutect2, varscan2
- LBP | c.-2G>C | 5'UTR (SNP) | VAF 11/69 reads (16%) | catalogued as COSV99460878; called by muse, mutect2, varscan2
- MFSD4B | c.*971G>A | 3'UTR (SNP) | VAF 35/74 reads (47%) | catalogued as COSV64348826; called by muse, mutect2, varscan2
- NACA | c.70+3979C>T | Intron (SNP) | VAF 3/18 reads (17%) | catalogued as COSV63270020; called by muse, mutect2
- SSPOP | n.9793C>T | RNA (SNP) | VAF 9/52 reads (17%) | catalogued as rs375572634, COSV65127900; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 9/21 reads (43%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- TBC1D32 | c.2571-9449G>C | Intron (SNP) | VAF 7/33 reads (21%) | catalogued as COSV51543155; called by muse, mutect2, varscan2
- XIRP2 | c.*539C>G | 3'UTR (SNP) | VAF 26/88 reads (30%) | catalogued as COSV54699864; called by muse, mutect2, varscan2
- ZFP36L1 | chr14:68796176 G>A | 5'Flank (SNP) | VAF 7/39 reads (18%) | catalogued as rs771102502; called by muse, mutect2, varscan2
